Somatic mutation profile of tumor specimen TCGA-61-2612-01A (aliquot TCGA-61-2612-01A-01W-1092-09) from TCGA case TCGA-61-2612, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.2 years (23,074 days).
Specimen TCGA-61-2612-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7efe0dee-d087-4790-ae10-dc8370c26347.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-61-2612-11A (Solid Tissue Normal), aliquot TCGA-61-2612-11A-01W-1092-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0ecc97b6-0488-4f92-b4fd-cd40491838fb

The open-access MAF lists 38 somatic variants for this specimen: 24 protein-altering or splice-affecting, 12 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 12, RNA 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 123/195 reads (63%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BLMH | c.112G>T p.D38Y | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV55585831; called by muse, mutect2, varscan2
- CC2D2A | c.1829C>T p.P610L | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs376457814, COSV67504048; ClinVar: uncertain significance; called by muse, varscan2
- CD36 | c.247A>T p.I83F | Missense Mutation (SNP) | VAF 18/109 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.446); catalogued as COSV59214334; called by muse, mutect2, varscan2
- CDAN1 | c.2407+1G>A p.X803_splice | Splice Site (SNP) | VAF 21/43 reads (49%) | catalogued as COSV62332577; called by muse, mutect2, varscan2
- CHMP2A | c.359C>A p.P120H | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53397140; called by muse, mutect2, varscan2
- CTPS1 | c.428G>C p.C143S | Missense Mutation (SNP) | VAF 15/542 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101009345; called by muse, mutect2
- DENND5B | c.3200A>G p.K1067R | Missense Mutation (SNP) | VAF 18/266 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100171609; called by muse, mutect2
- EPHA6 | c.545G>C p.R182P | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.842); catalogued as COSV67561570, COSV67568724, COSV67575935; called by muse, mutect2, varscan2
- ESPL1 | c.6290G>A p.R2097H | Missense Mutation (SNP) | VAF 41/178 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1230962687, COSV54476178; called by muse, mutect2, varscan2
- GABRE | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.033); catalogued as rs763903550, COSV64819982; called by muse, mutect2, varscan2
- GRID1 | c.807T>A p.D269E | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60018081, COSV60034080; called by muse, varscan2
- GUCY2C | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 54/531 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs756518777, COSV53791446; called by muse, mutect2, varscan2
- HID1 | c.1706C>T p.T569M | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.751); catalogued as rs373062583, COSV59351707; called by muse, mutect2, varscan2
- NUP35 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 35/273 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs766488860, COSV54558317; called by muse, mutect2, varscan2
- NUTM2D | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV67746472; called by muse, mutect2, varscan2
- PCDHB4 | c.1111G>A p.D371N | Missense Mutation (SNP) | VAF 44/103 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52023523, COSV52024096; called by muse, mutect2, varscan2
- PPRC1 | c.4199G>A p.R1400Q | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs748036766, COSV53386165, COSV99531266; called by muse, mutect2, varscan2
- PRDM9 | c.336G>T p.Q112H | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV99690576; called by muse, mutect2
- PXDNL | c.1873A>T p.I625F | Missense Mutation (SNP) | VAF 34/254 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.762); catalogued as COSV62490018; called by muse, mutect2, varscan2
- SLC8A3 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 65/108 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772541433, COSV63521290; called by muse, mutect2, varscan2
- TC2N | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61747226; called by muse, mutect2, varscan2
- TINAGL1 | c.1186C>T p.R396W | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1287871110, COSV99592930; called by mutect2, varscan2
- ZER1 | c.1055A>C p.N352T | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.956); catalogued as COSV52566365; called by muse, mutect2, varscan2
- ATG2B | c.1809C>T p.S603= | Silent (SNP) | VAF 27/151 reads (18%) | catalogued as COSV63423781; called by muse, mutect2, varscan2
- BCHE | c.813G>T p.T271= | Silent (SNP) | VAF 32/145 reads (22%) | catalogued as rs1398040946, COSV52257855; called by muse, mutect2, varscan2
- CIC | c.4251C>T p.R1417= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV50592568; called by muse, mutect2
- FAP | c.75C>T p.V25= | Silent (SNP) | VAF 29/189 reads (15%) | catalogued as rs1238391391, COSV51862945; called by muse, mutect2, varscan2
- LGALS9 | c.780T>G p.S260= (on ENST00000395473 / NM_009587.3; = p.S228= on NM_002308.4) | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as COSV56349316; called by muse, mutect2, varscan2
- LPAR5 | c.228C>T p.P76= | Silent (SNP) | VAF 13/109 reads (12%) | catalogued as COSV61692631; called by muse, mutect2, varscan2
- LRFN5 | c.444C>A p.A148= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs766394946, COSV53260986; called by muse, mutect2, varscan2
- MSH4 | c.603T>G p.L201= | Silent (SNP) | VAF 27/140 reads (19%) | catalogued as COSV54204735; called by muse, mutect2, varscan2
- NMUR1 | c.607C>A p.R203= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV59403469, COSV59404620; called by muse, varscan2
- PPP2R5D | c.885C>T p.N295= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as rs768102492, COSV99776556; called by muse, mutect2, varscan2
- WSCD1 | c.1443C>T p.Y481= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as rs142363588; called by muse, mutect2
- ZNF529 | c.1314T>A p.T438= | Silent (SNP) | VAF 79/916 reads (9%) | catalogued as rs1568570274, COSV100485282; called by muse, mutect2
- MIR1269A | n.36C>T | RNA (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- MRPS17P9 | n.22G>A | RNA (SNP) | VAF 19/133 reads (14%) | catalogued as rs183014448; called by muse, mutect2, varscan2
